FM case AD16187 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Esophagus.
https://portal.gdc.cancer.gov/cases/0b3dbf59-cf92-4041-9b32-e78ec5543125

Male, 60.6 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the esophagus; primary biopsied or resected from the esophagus. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
